Gene-level copy-number profile of specimen HCM-CSHL-0405-C25-85A from HCMI case HCM-CSHL-0405-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 48.3 years (17,648 days).
Specimen HCM-CSHL-0405-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6faacc23-df2b-4f0d-ad0d-f98ccab36bd5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0405-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/fdfe1ec2-c5d6-4759-90ee-e79b19ffdb48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,281; copy number 2: 40,084; copy number 3: 4,376; copy number 4: 907; copy number 5: 160; copy number 6: 45; copy number 7: 57; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 263 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,556,069–11,771,350, 1 gene, copy number 5 (within-gene range 1–5): VGLL4.
- chr3:11,790,442–13,638,422, 38 genes, copy number 5–9: TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2.
- chr10:73,497,538–74,709,963, 42 genes, copy number 6 (within-gene range 3–6): USP54, RNU6-883P, RPS26P41, AC073389.1, AC073389.3, MYOZ1, SYNPO2L, AC073389.2, AGAP5, BMS1P4-AGAP5, BMS1P4, AC022400.4, RNA5SP320, BMS1P4, GLUD1P3, DUSP8P5, AC022400.3, AC022400.6, SEC24C, AC022400.7, FUT11, CHCHD1, ZSWIM8, AC022400.8, ZSWIM8-AS1, AC022400.5, NDST2, CAMK2G, AC022400.1, AC022400.2, PLAU, C10orf55, VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA.
- chr10:76,558,350–84,561,263, 125 genes, copy number 5–6 (within-gene range 3–7) (broad region; genes not listed).
- chr19:38,797,002–39,607,474, 57 genes, copy number 7: RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13.

Autosomal genes at a single copy (total copy number 1): 10,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
